Gene-level copy-number profile of tumor specimen TCGA-20-1683-01A from TCGA case TCGA-20-1683, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 65.7 years (24,006 days).
Specimen TCGA-20-1683-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.504b5d05-7e0b-40ff-ad58-fcb5ce50edb3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-20-1683-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2a2ed8ac-76ef-49e1-a7e0-8e83f4408eff

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 3,261; copy number 2: 19,029; copy number 3: 24,569; copy number 4: 5,905; copy number 5: 5,640; copy number 6: 1,067; copy number 8: 297; copy number 9: 12; copy number 24: 7; copy number 31: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-20-1683-01A-01D-0559-01): tumor purity 0.89, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 332 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:125,466,939–130,017,129, 64 genes, copy number 8 (within-gene range 5–8) (broad region; genes not listed).
- chr8:133,325,997–137,092,183, 43 genes, copy number 8–9 (within-gene range 5–9): KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, AC103955.1, AC023781.1.
- chr11:73,157,946–74,171,210, 35 genes, copy number 8: AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1.
- chr19:13,731,760–16,103,002, 137 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr19:29,698,886–30,713,538, 15 genes, copy number 9–24 (within-gene range 3–24): C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536.
- chr19:34,404,399–34,686,397, 16 genes, copy number 31: PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP, RPS26P55, ZNF807P, SCGB1B2P, SCGB2B2, AC020910.4, AC020910.1, AC020910.2, AC020910.7, SCGB2B3P, AC020910.6, ZNF302.
- chr20:50,081,124–50,691,542, 22 genes, copy number 8: UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.

Autosomal genes at a single copy (total copy number 1): 1,946. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
